Somatic mutation profile of tumor specimen TCGA-AG-A014-01A (aliquot TCGA-AG-A014-01A-02W-A00K-09) from TCGA case TCGA-AG-A014, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 86.8 years (31,718 days).
Specimen TCGA-AG-A014-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb44e94b-8fab-406c-be3b-4945a0c1b53e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A014-10A (Blood Derived Normal), aliquot TCGA-AG-A014-10A-01W-A00K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/931d6963-3bcf-4747-bc39-e8a3142656fc

The open-access MAF lists 102 somatic variants for this specimen: 79 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 19, Nonsense Mutation 4, Frame Shift Ins 2, Intron 2, Splice Region 1, Frame Shift Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 23/34 reads (68%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, varscan2
- TP53 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 36/56 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1057520005, COSV52707923, COSV52708386, COSV52728497, COSV53727597; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACADL | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as rs1207370149, COSV52055421; called by muse, mutect2, varscan2
- ACIN1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99399276; called by muse, mutect2, varscan2
- ADAMTS12 | c.1433G>T p.C478F | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61260455; called by muse, mutect2, varscan2
- ADGRF2 | c.764T>C p.F255S (on ENST00000296862 / NM_001368115.2; = p.F187S on NM_153839.7) | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV57287756; called by muse, mutect2, varscan2
- ADORA2A | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as COSV58378608; called by muse, mutect2, varscan2
- AHCYL2 | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as COSV100273161; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2980G>A p.D994N | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.532); catalogued as rs1301002746, COSV99782569; called by muse, mutect2
- APC | c.3625G>T p.E1209* | Nonsense Mutation (SNP) | VAF 41/187 reads (22%) | catalogued as CD011096, COSV57327136; called by muse, mutect2, varscan2
- APC | c.4233del p.S1411Rfs*4 | Frame Shift Del (DEL) | VAF 111/215 reads (52%) | catalogued as COSV57321189; called by mutect2, varscan2
- ATP5F1A | c.254A>G p.H85R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV56360080, COSV56360152; called by muse, mutect2, varscan2
- CACNA1E | c.5101G>A p.V1701M | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs762078001, COSV62389873; called by muse, mutect2, varscan2
- CDIN1 | c.304C>G p.L102V (on ENST00000437989; = p.L4V on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV57710743; called by muse, mutect2, varscan2
- CHSY3 | c.1301T>A p.L434H | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100518741; called by muse, mutect2, varscan2
- CIB4 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs887212934, COSV56600175; called by muse, mutect2, varscan2
- COPS7A | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV99976413; called by muse, mutect2, varscan2
- DISP1 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755807282, COSV52657439; called by muse, mutect2, varscan2
- DST | c.17092G>C p.E5698Q (on ENST00000361203 / NM_001374722.1; = p.E3395Q on NM_015548.5) | Missense Mutation (SNP) | VAF 88/236 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as COSV55008276; called by muse, mutect2, varscan2
- DVL3 | c.978G>A p.P326= | Splice Region (SNP) | VAF 17/78 reads (22%) | catalogued as rs186597752, COSV57455665, COSV57457667; called by muse, mutect2, varscan2
- EBF2 | c.1316C>G p.S439* | Nonsense Mutation (SNP) | VAF 54/73 reads (74%) | catalogued as COSV68777077; called by muse, mutect2, varscan2
- ESD | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV66339987; called by muse, mutect2, varscan2
- EXOC4 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 40/398 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs372024692; called by muse, mutect2
- EYS | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.554); catalogued as COSV100676026; called by muse, mutect2, varscan2
- FERMT3 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs139416960, COSV54181562; called by muse, mutect2, varscan2
- FEZ1 | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.137); catalogued as COSV99630405; called by muse, mutect2, varscan2
- FOXI1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as COSV60388069, COSV60388451; called by muse, varscan2
- GCOM1 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.566); catalogued as rs772067728, COSV51092886; called by muse, mutect2, varscan2
- GFRA1 | c.514T>A p.S172T | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100815581; called by muse, mutect2, varscan2
- HEATR1 | c.3732G>T p.E1244D | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV63984136; called by muse, mutect2, varscan2
- HYAL4 | c.64T>C p.W22R | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99772123; called by muse, mutect2, varscan2
- ITGA10 | c.443C>A p.S148* | Nonsense Mutation (SNP) | VAF 156/537 reads (29%) | catalogued as COSV100994786; called by muse, mutect2, varscan2
- ITIH3 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.255); catalogued as rs747148462, COSV69648464; called by muse, mutect2
- JAKMIP2 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54600699, COSV54601846; called by muse, mutect2, varscan2
- KCNAB3 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 68/89 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as rs535006786, COSV100366369, COSV58050096; called by muse, mutect2, varscan2
- KCNB2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV73050373; called by muse, mutect2
- KCNG1 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100857022; called by muse, mutect2
- KCNIP1 | c.622G>T p.E208* (on ENST00000411494 / NM_001034837.3; = p.E197* on NM_014592.4) | Nonsense Mutation (SNP) | VAF 20/146 reads (14%) | catalogued as COSV61083308; called by muse, mutect2, varscan2
- KIAA1217 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 115/315 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56815276; called by muse, mutect2, varscan2
- LRP2 | c.7085G>A p.G2362E | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV55549665; called by muse, mutect2, varscan2
- LRRC7 | c.3463G>A p.D1155N (on ENST00000651989 / NM_001370785.2; = p.D1122N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.885); catalogued as rs1440012256, COSV50458449, COSV99225433; called by muse, mutect2, varscan2
- LY6D | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs769479466, COSV56660984; called by muse, mutect2, varscan2
- NDUFS2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100917387; called by muse, mutect2, varscan2
- NFXL1 | c.1460C>A p.P487H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV100216666; called by muse, mutect2, varscan2
- NPAP1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1020880302, COSV61506026; called by muse, mutect2, varscan2
- NRXN3 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs767157849, COSV59793551; called by muse, mutect2, varscan2
- OR51I2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 112/226 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs746240729, COSV58298444; called by muse, mutect2, varscan2
- PGM3 | c.1592C>A p.A531D | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52284452, COSV99381314; called by muse, mutect2, varscan2
- PHF1 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.988); catalogued as rs147032936, COSV99538967; called by muse, mutect2, varscan2
- PLA2G4D | c.174G>C p.K58N | Missense Mutation (SNP) | VAF 191/235 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs767678076, COSV99299418; called by muse, mutect2, varscan2
- PLCL1 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 113/196 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374856574; called by muse, mutect2, varscan2
- PON2 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs1244599987, COSV56001338; called by muse, mutect2, varscan2
- PRPF8 | c.5428T>G p.F1810V | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517272; called by muse, mutect2, varscan2
- PRTG | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs773682994, COSV66837585; called by muse, mutect2, varscan2
- PSMC5 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99856302; called by muse, mutect2, varscan2
- RBFOX1 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60955737; called by muse, mutect2, varscan2
- RETSAT | c.232G>C p.G78R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55525636; called by muse, mutect2, varscan2
- RXFP2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as rs765460875, COSV100034137; called by muse, mutect2, varscan2
- SCN2B | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as COSV54050396; called by muse, mutect2, varscan2
- SLC14A2 | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs779206322, COSV54911486; called by muse, mutect2, varscan2
- SLC2A10 | c.1532A>G p.Q511R | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100826342; called by muse, mutect2, varscan2
- SLC6A13 | c.962A>G p.N321S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs746122946, COSV100569833; called by muse, mutect2, varscan2
- SLFN5 | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV55480625; called by muse, mutect2, varscan2
- SLITRK1 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 219/315 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV100999864; called by muse, mutect2, varscan2
- SLITRK5 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 118/458 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs370073384; called by muse, mutect2, varscan2
- SPTY2D1 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100311559; called by mutect2, varscan2
- TOPORS | c.1119T>G p.N373K | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as COSV62116658; called by muse, mutect2, varscan2
- TRAPPC11 | c.2534G>A p.C845Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58215823; called by muse, mutect2, varscan2
- TRIP11 | c.2443A>G p.I815V | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50916492, COSV50917291; called by muse, mutect2, varscan2
- TSHZ3 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 66/751 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs777524623, COSV53668881, COSV99552976; called by muse, mutect2
- XKRX | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 122/567 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV60707763; called by muse, mutect2, varscan2
- ZEB2 | c.2869C>T p.R957W | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1354236085, COSV57955107, COSV57965320; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFYVE26 | c.2211G>T p.Q737H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV100720215; called by muse, mutect2
- ZNF292 | c.7377T>G p.N2459K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV60538084; called by muse, mutect2, varscan2
- ZNF605 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 198/315 reads (63%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV100053519; called by muse, mutect2, varscan2
- IGHV4-59 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.041); called by muse, varscan2
- PPP2R3A | c.91_92dup p.T32Afs*38 | Frame Shift Ins (INS) | VAF 52/187 reads (28%) | called by mutect2, pindel, varscan2
- RGMB | c.1238dup p.N413Kfs*9 (on ENST00000513185 / NM_001366508.1; = p.N454Kfs*9 on NM_001012761.3 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 21/46 reads (46%) | called by mutect2, pindel, varscan2
- SPX | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2
- ABCC3 | c.3189A>G p.T1063= | Silent (SNP) | VAF 11/119 reads (9%) | called by mutect2, varscan2
- CD53 | c.357C>T p.T119= | Silent (SNP) | VAF 42/172 reads (24%) | catalogued as rs201211085, COSV54760880, COSV99602038; called by muse, mutect2, varscan2
- CPOX | c.1035G>A p.P345= | Silent (SNP) | VAF 80/138 reads (58%) | catalogued as rs752340562, COSV99939062; called by muse, mutect2, varscan2
- CYP4B1 | c.1038C>T p.R346= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as rs762334759, COSV54723544; called by muse, mutect2, varscan2
- DNAH5 | c.2868C>T p.R956= | Silent (SNP) | VAF 116/221 reads (52%) | catalogued as rs767246326, COSV54204914; called by muse, mutect2, varscan2
- FOCAD | c.3135G>A p.T1045= | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as rs775718721, COSV100620184; called by muse, mutect2, varscan2
- FZD7 | c.1650G>A p.S550= | Silent (SNP) | VAF 53/64 reads (83%) | catalogued as COSV99636984; called by muse, mutect2, varscan2
- IL12A | c.159C>T p.L53= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1318535700, COSV59759670; called by muse, mutect2, varscan2
- KRT37 | c.546G>A p.A182= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs778746683, COSV56657409; called by muse, mutect2, varscan2
- LYST | c.10188G>A p.Q3396= | Silent (SNP) | VAF 10/246 reads (4%) | catalogued as COSV101088706; called by muse, mutect2
- MYF5 | c.462G>A p.S154= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs751777341, COSV57354383; called by muse, mutect2, varscan2
- NSD1 | c.7332G>A p.Q2444= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as COSV100728611; called by muse, mutect2, varscan2
- NSMAF | c.540A>G p.T180= | Silent (SNP) | VAF 74/313 reads (24%) | catalogued as rs1208933094, COSV99232553; called by muse, mutect2, varscan2
- PDE3A | c.1857T>A p.A619= | Silent (SNP) | VAF 16/251 reads (6%) | catalogued as COSV100761964; called by muse, mutect2
- PSD2 | c.1086C>T p.D362= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs747518596, COSV51199034; called by muse, mutect2, varscan2
- SLC13A1 | c.330G>A p.L110= | Silent (SNP) | VAF 93/385 reads (24%) | catalogued as rs1348916225, COSV52010095; called by muse, mutect2, varscan2
- ZBTB8A | c.1215G>A p.E405= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs1343275188, COSV57142305; called by muse, mutect2, varscan2
- ZCWPW1 | c.588G>A p.K196= | Silent (SNP) | VAF 23/199 reads (12%) | catalogued as rs1383171253, COSV61248698; called by muse, mutect2, varscan2
- ZNF160 | c.1698G>A p.K566= | Silent (SNP) | VAF 36/222 reads (16%) | catalogued as rs1381849893, COSV62000924; called by muse, varscan2
- C7orf66 | n.349C>G | RNA (SNP) | VAF 71/484 reads (15%) | called by muse, mutect2, varscan2
- DST | c.21999+427C>T | Intron (SNP) | VAF 24/46 reads (52%) | catalogued as rs768405206, COSV55008268; called by muse, mutect2, varscan2
- NRG1 | c.700+663G>A | Intron (SNP) | VAF 61/89 reads (69%) | catalogued as rs767932599, COSV55154941; called by muse, mutect2, varscan2
- TXNDC8 | c.-1C>T | 5'UTR (SNP) | VAF 5/64 reads (8%) | catalogued as COSV65725507; called by muse, mutect2
